Somatic mutation profile of tumor specimen TCGA-97-A4LX-01A (aliquot TCGA-97-A4LX-01A-11D-A24P-08) from TCGA case TCGA-97-A4LX, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.9 years (29,915 days).
Specimen TCGA-97-A4LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42c632bc-1a83-49b5-8a58-dcbd452aa967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-A4LX-10A (Blood Derived Normal), aliquot TCGA-97-A4LX-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7147b412-20da-4617-93db-29578230b4af

The open-access MAF lists 188 somatic variants for this specimen: 139 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 44, Nonsense Mutation 11, RNA 4, Intron 1, Splice Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV100735759, COSV62929473; called by muse, mutect2, varscan2
- ADAMTS12 | c.2319G>T p.Q773H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.246); catalogued as rs988925155, COSV100710783; called by muse, mutect2
- ADAMTS8 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99960836; called by muse, mutect2
- ADGRD1 | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99895162; called by muse, mutect2, varscan2
- ADH1A | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV52926429; called by muse, mutect2
- AKNA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.537); catalogued as rs571164651, COSV56337417, COSV99799467; called by muse, mutect2
- ANGPT4 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV101124709; called by muse, mutect2, varscan2
- ANK1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV55894008, COSV99224960; called by muse, mutect2
- ANK2 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100001237; called by muse, mutect2
- ATP2B4 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100397431; called by muse, mutect2, varscan2
- BAP1 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV56231488; called by muse, mutect2, varscan2
- C1orf74 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV99161071; called by muse, mutect2, varscan2
- CCDC22 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV100544700; called by muse, mutect2
- CDC20B | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99696832; called by muse, mutect2
- CDC25C | c.1289A>C p.Q430P | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100086686; called by muse, mutect2
- CDH10 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 14/244 reads (6%) | catalogued as COSV52595451; called by muse, mutect2
- CDH6 | c.2310G>T p.W770C | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418930; called by muse, mutect2
- CDH7 | c.2001C>G p.D667E | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100542174; called by muse, mutect2, varscan2
- CDH9 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 18/125 reads (14%) | catalogued as COSV99143944; called by muse, varscan2
- CEP162 | c.4120G>T p.D1374Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002721; called by muse, mutect2, varscan2
- CFAP61 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV99844530; called by muse, mutect2, varscan2
- CHFR | c.1186C>T p.R396W (on ENST00000432561 / NM_001161345.1; = p.R355W on NM_018223.2) | Missense Mutation (SNP) | VAF 31/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920205326, COSV57174795; called by muse, mutect2
- CLEC1B | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV100046048; called by muse, mutect2
- CPED1 | c.2404G>T p.G802C | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100120571; called by muse, mutect2
- DCSTAMP | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99886053, COSV99886505; called by muse, mutect2, varscan2
- DIP2B | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998373; called by muse, mutect2
- DLG5 | c.4216A>T p.T1406S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV100967434; called by muse, mutect2
- DMRT3 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1249995026, COSV99505824; called by muse, mutect2
- DPEP3 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99262676; called by muse, mutect2
- ENOX1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99815788; called by muse, mutect2, varscan2
- EPAS1 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV99763147; called by muse, mutect2, varscan2
- EPHA6 | c.2423C>A p.P808H (on ENST00000389672 / NM_001080448.3; = p.P200H on NM_173655.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.91); catalogued as COSV101062241; called by muse, mutect2, varscan2
- EPHB6 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101235970; called by muse, mutect2, varscan2
- EXOSC8 | c.830A>T p.*277Lext*16 | Nonstop Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99524027; called by muse, mutect2, varscan2
- F3 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV100474233; called by muse, mutect2
- FAM47C | c.1084C>A p.R362S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.302); catalogued as COSV100792483, COSV63726760; called by muse, mutect2, varscan2
- FAT4 | c.10082G>T p.G3361V | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100626770, COSV100628399; called by muse, mutect2, varscan2
- FIGN | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1466279727, COSV100292244; called by muse, mutect2
- FRMPD1 | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); catalogued as COSV100899543; called by muse, mutect2, varscan2
- FRS2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as rs1048144608, COSV54729019; called by muse, mutect2
- GABRA6 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99194349; called by muse, mutect2
- GBA2 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803374; called by muse, mutect2
- GLRA3 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56858953, COSV99927484; called by muse, mutect2
- GPR142 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100170797; called by muse, mutect2, varscan2
- GTF3C1 | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV100649348, COSV62239692; called by muse, mutect2
- H2AC11 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV100345723; called by muse, mutect2, varscan2
- H3-4 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100797382, COSV64211232; called by muse, mutect2, varscan2
- HBG2 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100400592, COSV100400758; called by mutect2, varscan2
- HCFC2 | c.2357A>G p.N786S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs950318999, COSV99983004; called by muse, mutect2, varscan2
- HHIPL2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100596805; called by muse, mutect2
- HOXD10 | c.343A>T p.M115L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV99982698; called by muse, mutect2
- IRX6 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV51859859, COSV99306412; called by muse, mutect2
- ITM2A | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100964446, COSV100964478; called by muse, mutect2, varscan2
- KCNC2 | c.1149G>T p.L383F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV100128699; called by muse, mutect2, varscan2
- KCNH6 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.141); catalogued as COSV100120977; called by muse, mutect2
- KCNN2 | c.1510G>T p.E504* (on ENST00000264773; = p.E716* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | catalogued as COSV99299572; called by muse, mutect2
- KCNV1 | c.1223T>A p.V408E | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV99819043; called by muse, mutect2, varscan2
- KDR | c.1978A>T p.T660S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99817465; called by muse, mutect2, varscan2
- KLHL4 | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100909484; called by muse, mutect2
- KLK15 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV100032706; called by muse, mutect2, varscan2
- KRT73 | c.1043A>G p.N348S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV59839502, COSV99988477; called by muse, mutect2
- LIPI | c.840G>T p.L280F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV60710032; called by muse, mutect2, varscan2
- LOX | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as COSV50237346; called by muse, mutect2
- LRP1B | c.1951G>T p.V651L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV101255986; called by muse, mutect2, varscan2
- LRRTM2 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99217760; called by muse, mutect2, varscan2
- MAGEB6 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV66872159; called by muse, mutect2, varscan2
- MAN2A1 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99810945; called by muse, mutect2, varscan2
- MAP4 | c.2153A>G p.K718R | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99275212; called by muse, mutect2
- MGA | c.6718G>T p.E2240* (on ENST00000219905 / NM_001164273.1; = p.E2031* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99579667; called by muse, mutect2, varscan2
- MUC16 | c.12877T>A p.S4293T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.263); catalogued as COSV101199616; called by muse, mutect2
- NSUN4 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV100197464; called by muse, mutect2
- OBSCN | c.9406C>G p.R3136G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV99476923; called by muse, mutect2, varscan2
- OR10H5 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100454699; called by muse, mutect2, varscan2
- OR2F2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV101283812; called by muse, mutect2, varscan2
- OR4K5 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs577596436, COSV100262340; called by muse, mutect2
- OR5B21 | c.808A>T p.I270L | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as COSV100835143; called by muse, mutect2
- OR5W2 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs372261435; called by muse, mutect2, varscan2
- PCDH18 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100787268; called by muse, mutect2
- PER3 | c.1633A>T p.R545* | Nonsense Mutation (SNP) | VAF 21/199 reads (11%) | catalogued as COSV100728314; called by muse, mutect2
- PEX1 | c.274-1G>T p.X92_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as CS1111361; called by muse, mutect2
- PGAP4 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV100877824; called by muse, mutect2
- PGAP4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs748623996, COSV100877826; called by muse, mutect2, varscan2
- POTEF | c.2358G>T p.W786C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1413098083, COSV100664848, COSV99051466; called by muse, mutect2
- POTEF | c.2357G>T p.W786L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV100664849; called by muse, mutect2
- PPM1A | c.306A>T p.R102S | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100349022; called by muse, mutect2
- PRKACB | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100853922; called by muse, mutect2
- RAB6B | c.468T>A p.S156R | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99557960; called by muse, mutect2
- RABGAP1 | c.2685G>C p.L895F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV101016806; called by muse, mutect2, varscan2
- RC3H1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99281308; called by muse, mutect2
- RELN | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.073); catalogued as COSV100633483; called by muse, mutect2
- RILP | c.1075A>T p.T359S | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.196); catalogued as COSV99557007; called by muse, mutect2
- RTRAF | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910872; called by muse, mutect2, varscan2
- SAXO2 | c.959G>T p.R320I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs751276624, COSV100255685; called by muse, mutect2
- SCLY | c.410G>T p.S137I (on ENST00000651534; = p.S129I on NM_016510.7) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99615596; called by muse, mutect2, varscan2
- SEMA3A | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99546329; called by muse, mutect2, varscan2
- SEMA3C | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99542865; called by muse, mutect2
- SEMA3F | c.1637A>G p.H546R | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256660804; called by muse, mutect2
- SIPA1L2 | c.3314G>T p.R1105L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV99478032; called by muse, mutect2, varscan2
- SLC16A7 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1473111651, COSV53898220; called by muse, mutect2
- SLC4A7 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99839652; called by muse, mutect2
- SLC5A11 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as COSV100762762; called by muse, mutect2, varscan2
- SLCO5A1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99479892, COSV99481353; called by muse, mutect2, varscan2
- SMC2 | c.1651A>G p.N551D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99658861; called by muse, mutect2
- SMPX | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101069784; called by muse, mutect2, varscan2
- SNTB1 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as COSV101179997; called by muse, mutect2
- SPHKAP | c.4780G>T p.A1594S (on ENST00000392056 / NM_001142644.2; = p.A1565S on NM_030623.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.355); catalogued as COSV60870756, COSV60872374; called by muse, mutect2
- SPTA1 | c.4562C>A p.P1521H | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100934790; called by muse, mutect2, varscan2
- SRPX | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100656030, COSV59442062; called by muse, mutect2, varscan2
- STK38L | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV101198765, COSV66520972; called by muse, mutect2
- STON2 | c.1289G>T p.S430I (on ENST00000649389 / NM_001366849.2; = p.S373I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99964687, COSV99965283; called by muse, mutect2, varscan2
- SUCO | c.2359A>G p.I787V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99742668; called by muse, mutect2, varscan2
- TACR3 | c.1248C>A p.N416K | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV100510378, COSV99072676; called by muse, mutect2, varscan2
- TANC1 | c.2329A>G p.I777V | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs1559404860, COSV99713760; called by muse, mutect2
- TBC1D23 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009398172, COSV100792554; called by muse, mutect2
- TET1 | c.2023A>G p.S675G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs141988009; called by muse, mutect2, varscan2
- TFRC | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as rs1314259682, COSV100786448; called by muse, mutect2, varscan2
- TGM4 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99942270; called by muse, mutect2, varscan2
- THOC6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV50187420; called by muse, mutect2, varscan2
- TNR | c.2719G>C p.D907H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1340736640, COSV99689250; called by muse, mutect2
- TPK1 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100765623; called by muse, mutect2, varscan2
- TRPC4 | c.1059C>A p.S353R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100156661; called by muse, mutect2, varscan2
- TRPC6 | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100723575; called by muse, mutect2, varscan2
- TRPS1 | c.254G>T p.G85V (on ENST00000220888 / NM_001330599.2; = p.G98V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV99630254; called by muse, mutect2, varscan2
- TUBB6 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99301813; called by muse, mutect2
- UGT2B11 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101485245; called by muse, varscan2
- WDR88 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV50121340; called by muse, mutect2
- ZFHX4 | c.9330_9331insA p.G3111Rfs*80 | Frame Shift Ins (INS) | VAF 15/97 reads (15%) | catalogued as COSV99261949; called by mutect2, pindel, varscan2
- ZFPM2 | c.3140G>T p.G1047V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101023191; called by muse, mutect2, varscan2
- ZNF16 | c.1754G>T p.S585I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV99429619; called by muse, mutect2, varscan2
- ZNF521 | c.1931C>A p.T644K | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV100831985; called by muse, mutect2
- ZNF780B | c.2317A>G p.S773G | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99665607; called by muse, mutect2, varscan2
- ZNF804A | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100167537; called by muse, mutect2, varscan2
- ANK2 | c.11264G>T p.G3755V | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASR | c.1526C>A p.P509Q (on ENST00000490131; = p.P586Q on NM_000388.4) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CFAP74 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ESYT1 | c.1889C>G p.A630G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGKV3D-11 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by mutect2, varscan2
- MRC1 | c.2726G>T p.W909L | Missense Mutation (SNP) | VAF 27/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PIWIL2 | c.894C>A p.D298E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2
- ACCSL | c.1596T>C p.F532= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV101122179; called by muse, mutect2, varscan2
- AKAP3 | c.1479C>T p.S493= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV57413746; called by muse, mutect2
- AKR1B10 | c.621T>A p.V207= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100610181; called by muse, mutect2, varscan2
- APOB | c.11340C>T p.A3780= | Silent (SNP) | VAF 21/224 reads (9%) | catalogued as COSV99265291; called by muse, mutect2
- ARHGAP36 | c.1599C>G p.P533= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99357617; called by muse, mutect2, varscan2
- ATP6V1H | c.669G>A p.G223= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV100778635; called by muse, mutect2
- CD3D | c.279C>T p.C93= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as CM042954, COSV99416647; called by muse, mutect2, varscan2
- DICER1 | c.4698G>T p.L1566= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV100602024; called by muse, mutect2
- FAM135B | c.759G>T p.R253= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV99423020; called by muse, mutect2, varscan2
- FER1L6 | c.5475C>A p.I1825= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as COSV101205781; called by muse, mutect2, varscan2
- GGA2 | c.1047G>T p.L349= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100564664; called by muse, mutect2, varscan2
- GSDMA | c.279G>T p.V93= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV100053648, COSV56980443; called by muse, mutect2
- HELZ | c.4842C>T p.S1614= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV100698659, COSV62380045; called by muse, mutect2
- INTS4 | c.1770A>T p.P590= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV101417173; called by muse, mutect2, varscan2
- KCNH6 | c.417C>T p.C139= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100120976; called by muse, mutect2, varscan2
- KDM2B | c.2115A>T p.S705= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100997387; called by muse, mutect2, varscan2
- KLRC2 | c.654G>A p.Q218= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs541317905, COSV101122679; called by muse, mutect2
- KRR1 | c.399A>G p.V133= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99875650; called by muse, mutect2
- LAMB3 | c.3069G>T p.R1023= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99151673; called by muse, mutect2, varscan2
- NCOA6 | c.5487C>T p.T1829= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as COSV100749977; called by muse, mutect2, varscan2
- OCA2 | c.1261C>A p.R421= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100667606; called by mutect2, varscan2
- OR10J1 | c.483A>T p.T161= | Silent (SNP) | VAF 32/221 reads (14%) | catalogued as rs1343789741, COSV101419849; called by muse, mutect2, varscan2
- OR2L2 | c.69C>A p.G23= | Silent (SNP) | VAF 25/227 reads (11%) | catalogued as COSV100823532; called by muse, mutect2, varscan2
- OR8J3 | c.114C>A p.T38= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV100040753, COSV100040778; called by muse, mutect2, varscan2
- P2RY8 | c.279G>T p.V93= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101183997; called by muse, mutect2, varscan2
- PACRGL | c.486G>T p.V162= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV99764057; called by muse, mutect2
- PEAR1 | c.36T>A p.A12= | Silent (SNP) | VAF 25/170 reads (15%) | catalogued as COSV99441293; called by muse, mutect2, varscan2
- PEX5L | c.129C>A p.A43= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99828509; called by muse, mutect2
- PMFBP1 | c.1854A>T p.T618= (on ENST00000537465; = p.T613= on NM_031293.3) | Silent (SNP) | VAF 27/367 reads (7%) | catalogued as COSV99400740; called by muse, mutect2
- POF1B | c.93C>T p.H31= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs767045189, COSV99426585; called by muse, mutect2, varscan2
- PPP4R3A | c.2055A>T p.T685= (on ENST00000554943 / NM_001366432.1; = p.T672= on NM_001284280.1) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100465997; called by muse, mutect2, varscan2
- RSPO4 | c.513C>A p.G171= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV54081077; called by muse, mutect2
- RXFP2 | c.2025A>T p.I675= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100034269; called by muse, mutect2, varscan2
- SAXO2 | c.348A>T p.T116= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as COSV100255683; called by muse, mutect2, varscan2
- SI | c.3354A>G p.E1118= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100015282; called by muse, mutect2
- SIPA1L1 | c.1731G>T p.V577= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as COSV100665469; called by muse, mutect2, varscan2
- TAS2R40 | c.852C>T p.I284= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as COSV101282992; called by muse, mutect2
- TMEM176A | c.681G>A p.K227= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV99133685; called by muse, mutect2
- TMEM215 | c.663T>C p.Y221= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV100713168; called by muse, mutect2
- UEVLD | c.480A>T p.A160= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100260875; called by muse, mutect2, varscan2
- YEATS2 | c.1293A>T p.A431= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as COSV59367031; called by muse, mutect2, varscan2
- ZNF521 | c.1932A>T p.T644= | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV100831982; called by muse, mutect2
- ZNF572 | c.666G>T p.G222= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV100073929; called by muse, mutect2, varscan2
- ZNF804B | c.3621C>A p.T1207= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV100303470; called by muse, mutect2
- AGPAT4 | c.843+2306C>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1568G>A | RNA (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- DCHS2 | n.668C>A | RNA (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100251655; called by muse, mutect2
- FBXL21P | n.1070G>C | RNA (SNP) | VAF 11/121 reads (9%) | catalogued as COSV51808498, COSV99778285; called by muse, mutect2
- RPL26P30 | n.737T>G | RNA (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
